Somatic mutation profile of tumor specimen 0DI3LX from CCDI case PBBUNP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.2 years (72 days).
Specimen 0DI3LX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d44f663d-fc2e-438b-a2e3-2350d417652f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DI3J9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f0fcdd9e-8eae-46eb-aa6c-db9ff0a12eb9

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Splice Site 1, Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LIN9 | c.1639-2A>T p.X547_splice (on ENST00000366808 / NM_001270410.2; = p.X492_splice on NM_173083.3 and 5 other RefSeq transcripts) | Splice Site (SNP) | VAF 184/566 reads (33%) | catalogued as COSV60244106; called by muse, varscan2
- SPATA16 | c.1217C>T p.P406L | Missense Mutation (SNP) | VAF 80/745 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758801309, COSV63529138; called by muse, varscan2
- CNTD1 | c.921G>A p.P307= | Silent (SNP) | VAF 215/450 reads (48%) | catalogued as rs528385631; called by muse, varscan2
